Somatic mutation profile of tumor specimen TARGET-15-SJMPAL042794-09A.2 (aliquot TARGET-15-SJMPAL042794-09A.2-01D) from TARGET case TARGET-15-SJMPAL042794, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.2 years (5,541 days).
Specimen TARGET-15-SJMPAL042794-09A.2: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8af63ee-1c01-4760-b74f-cf7c0f969a7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL042794-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL042794-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f68b8e49-7864-4f58-ae86-781e2388a84a

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559986079; called by muse, mutect2, varscan2
- MGAT3 | c.1354C>A p.L452M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- TRIM69 | c.480C>A p.F160L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by mutect2, varscan2
